Gene-level copy-number profile of tumor specimen TCGA-AX-A2H8-01A from TCGA case TCGA-AX-A2H8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 64.2 years (23,448 days).
Specimen TCGA-AX-A2H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.ae782754-e5b2-4d0b-8ee4-46641e6b3a43.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A2H8-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/798e3ce9-5ec1-4b65-9797-4dcd17a0b4d2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 26; copy number 2: 13,135; copy number 3: 1,448; copy number 4: 39,837; copy number 5: 189; copy number 6: 2,569; copy number 7: 883; copy number 8: 364; copy number 9: 1,199; copy number 10: 4; copy number 11: 35; copy number 12: 16; copy number 14: 104.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AX-A2H8-01): tumor purity 0.77, ploidy 1.94, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:121,821,928–122,093,606, 1 gene (within-gene range 0–2): TTLL11.
- chr22:28,800,683–28,848,559, 2 genes (within-gene range 0–4): Z93930.2, Z93930.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,358 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,363,091–150,913,292, 27 genes, copy number 9 (within-gene range 7–9): RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51.
- chr5:20,967,211–25,445,925, 51 genes, copy number 11–12: AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2.
- chr7:138,831,381–138,981,389, 1 gene, copy number 9 (within-gene range 7–9): KIAA1549.
- chr7:139,025,706–139,483,673, 16 genes, copy number 9: ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2, RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1, RNU6-911P, KLRG2.
- chr15:97,572,185–101,820,197, 104 genes, copy number 14 (within-gene range 7–14) (broad region; genes not listed).
- chr16:24,803,451–25,257,845, 17 genes, copy number 9: AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1.
- chr19:10,718,079–10,833,488, 1 gene, copy number 9 (within-gene range 6–9): DNM2.
- chr19:10,780,254–19,192,591, 482 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr19:22,243,254–33,064,888, 199 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr19:52,222,020–58,315,183, 454 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:11,685,144–11,926,609, 6 genes, copy number 9–10: AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1.

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
